Somatic mutation profile of tumor specimen ALCH-B3A0-TTP1-A (aliquot ALCH-B3A0-TTP1-A-1-0-D-A799-36) from ALCHEMIST case ALCH-B3A0, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 60.1 years (21,935 days).
Specimen ALCH-B3A0-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 026157e7-4124-44bf-bce6-ab43f46702e1.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B3A0-NB1-A (Blood Derived Normal), aliquot ALCH-B3A0-NB1-A-1-0-D-A799-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/504d3d07-badc-4500-aa89-b2be61609681

The open-access MAF lists 541 somatic variants for this specimen: 368 protein-altering or splice-affecting, 119 silent, 54 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 306, Silent 119, Nonsense Mutation 23, Frame Shift Del 21, Intron 20, RNA 13, 3'UTR 10, Splice Site 8, 5'UTR 5, Frame Shift Ins 4, 3'Flank 3, Splice Region 3.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 103/355 reads (29%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.303); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.734G>A p.G245D | Missense Mutation (SNP) | VAF 80/331 reads (24%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121912656, CM010464, CM900209, COSV52666323, COSV52667838, COSV52745465; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- AARS2 | c.407A>G p.N136S | Missense Mutation (SNP) | VAF 86/820 reads (10%) | SIFT tolerated (0.28); PolyPhen benign (0.102); catalogued as rs781255698, COSV55115768; ClinVar: uncertain significance; called by muse, varscan2
- ACAN | c.676G>A p.E226K | Missense Mutation (SNP) | VAF 31/266 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.52); catalogued as rs749403999; called by muse, mutect2, varscan2
- ACAN | c.4532C>A p.S1511* | Nonsense Mutation (SNP) | VAF 52/290 reads (18%) | catalogued as COSV100717038; called by muse, mutect2, varscan2
- ADAMTS12 | c.2411C>A p.P804H | Missense Mutation (SNP) | VAF 36/157 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100710400; called by muse, mutect2, varscan2
- AKAP12 | c.219G>C p.E73D | Missense Mutation (SNP) | VAF 56/212 reads (26%) | SIFT tolerated (0.17); PolyPhen benign (0.006); catalogued as COSV53579379; called by muse, mutect2, varscan2
- ASB2 | c.517del p.V173* | Frame Shift Del (DEL) | VAF 10/78 reads (13%) | catalogued as COSV60112215; called by mutect2, pindel
- ASPSCR1 | c.1611_1613del p.R537del | In Frame Del (DEL) | VAF 9/35 reads (26%) | catalogued as rs1331872673; called by pindel, varscan2
- C1QTNF7 | c.56G>A p.R19Q | Missense Mutation (SNP) | VAF 91/490 reads (19%) | SIFT tolerated (0.3); PolyPhen benign (0.039); catalogued as rs890505562, COSV54852417; called by muse, mutect2, varscan2
- CACNA2D1 | c.612G>T p.L204F | Missense Mutation (SNP) | VAF 91/677 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.88); catalogued as rs1231904706; called by muse, mutect2, varscan2
- CASS4 | c.1184C>T p.P395L | Missense Mutation (SNP) | VAF 30/147 reads (20%) | SIFT tolerated (0.77); PolyPhen benign (0); catalogued as rs754801286; called by muse, mutect2, varscan2
- CEP128 | c.1198T>A p.S400T | Missense Mutation (SNP) | VAF 62/307 reads (20%) | SIFT tolerated (0.52); PolyPhen benign (0); catalogued as rs756236193; called by muse, mutect2, varscan2
- CFTR | c.4045G>A p.G1349S | Missense Mutation (SNP) | VAF 98/563 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs201686600, CM993872; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CLIP2 | c.280G>A p.V94M | Missense Mutation (SNP) | VAF 56/364 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs1554732626; called by muse, mutect2, varscan2
- CNTNAP2 | c.3685G>A p.D1229N | Missense Mutation (SNP) | VAF 66/469 reads (14%) | SIFT tolerated (0.43); PolyPhen benign (0.359); catalogued as rs143256141; called by muse, mutect2, varscan2
- COL22A1 | c.4012C>A p.P1338T | Missense Mutation (SNP) | VAF 47/334 reads (14%) | SIFT tolerated (0.07); PolyPhen benign (0.023); catalogued as rs149644599; called by muse, mutect2, varscan2
- COL22A1 | c.396C>A p.H132Q | Missense Mutation (SNP) | VAF 43/166 reads (26%) | SIFT tolerated (0.83); PolyPhen benign (0); catalogued as rs375825444; called by muse, mutect2, varscan2
- COL5A2 | c.2330G>A p.G777D | Missense Mutation (SNP) | VAF 110/705 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs957733276; called by muse, varscan2
- CSMD3 | c.8036C>G p.T2679R (on ENST00000297405 / NM_001363185.1; = p.T2575R on NM_052900.3) | Missense Mutation (SNP) | VAF 46/360 reads (13%) | SIFT tolerated (0.37); PolyPhen benign (0.133); catalogued as COSV52306358; called by muse, mutect2, varscan2
- CSMD3 | c.6520A>G p.T2174A (on ENST00000297405 / NM_001363185.1; = p.T2070A on NM_052900.3) | Missense Mutation (SNP) | VAF 19/395 reads (5%) | SIFT deleterious (0.05); PolyPhen benign (0.005); catalogued as rs1183480532; called by muse, mutect2
- CSMD3 | c.1728G>T p.W576C (on ENST00000297405 / NM_001363185.1; = p.W472C on NM_052900.3) | Missense Mutation (SNP) | VAF 58/256 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV99823322; called by muse, mutect2, varscan2
- CXCR5 | c.439C>T p.R147C | Missense Mutation (SNP) | VAF 19/96 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1200379234, COSV52683823; called by muse, mutect2, varscan2
- DGKB | c.2350C>A p.P784T | Missense Mutation (SNP) | VAF 34/231 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.879); catalogued as COSV51759473; called by muse, mutect2, varscan2
- DNAH5 | c.728T>C p.L243P | Missense Mutation (SNP) | VAF 53/337 reads (16%) | SIFT deleterious (0.03); PolyPhen benign (0.141); catalogued as COSV54245136; called by muse, mutect2, varscan2
- DRD1 | c.1079C>T p.T360M | Missense Mutation (SNP) | VAF 51/274 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.217); catalogued as rs753491559, COSV67104861; called by muse, mutect2, varscan2
- DROSHA | c.2159C>T p.A720V | Missense Mutation (SNP) | VAF 89/513 reads (17%) | SIFT tolerated (0.08); PolyPhen benign (0.001); catalogued as rs1215959799; called by muse, mutect2, varscan2
- EEF1A1 | c.325-1G>T p.X109_splice | Splice Site (SNP) | VAF 8/27 reads (30%) | catalogued as COSV58548535, COSV58549577; called by muse, mutect2
- F13B | c.1331G>T p.W444L | Missense Mutation (SNP) | VAF 37/284 reads (13%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as COSV100803542; called by muse, mutect2, varscan2
- F9 | c.1238del p.G413Dfs*13 | Frame Shift Del (DEL) | VAF 31/141 reads (22%) | catalogued as CM010292; called by mutect2, pindel, varscan2
- FAM126A | c.1083G>T p.Q361H | Missense Mutation (SNP) | VAF 37/154 reads (24%) | SIFT tolerated (0.2); PolyPhen benign (0.003); catalogued as rs138563857; called by muse, mutect2, varscan2
- FAM47A | c.2207C>T p.P736L | Missense Mutation (SNP) | VAF 16/99 reads (16%) | SIFT tolerated (0.06); PolyPhen benign (0.058); catalogued as rs1569241395, COSV60498310; called by muse, mutect2, varscan2
- FAM71B | c.1213G>A p.E405K | Missense Mutation (SNP) | VAF 12/336 reads (4%) | SIFT tolerated (0.07); PolyPhen benign (0.306); catalogued as rs1376753982; called by muse, mutect2
- FAT3 | c.3523C>A p.P1175T | Missense Mutation (SNP) | VAF 70/364 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99968519; called by muse, mutect2, varscan2
- FAT3 | c.9875G>T p.G3292V | Missense Mutation (SNP) | VAF 20/93 reads (22%) | SIFT tolerated (0.2); PolyPhen benign (0.001); catalogued as rs750201929; called by muse, mutect2, varscan2
- FBN2 | c.526G>C p.G176R | Missense Mutation (SNP) | VAF 48/360 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV52497833; called by muse, varscan2
- FER1L6 | c.4597C>A p.H1533N | Missense Mutation (SNP) | VAF 101/613 reads (16%) | SIFT tolerated (0.17); PolyPhen benign (0.195); catalogued as COSV67549640; called by muse, mutect2, varscan2
- FLT4 | c.88C>A p.P30T | Missense Mutation (SNP) | VAF 75/365 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99986028; called by muse, mutect2, varscan2
- FOXR1 | c.80G>T p.R27L | Missense Mutation (SNP) | VAF 16/478 reads (3%) | SIFT tolerated (0.08); PolyPhen benign (0.324); catalogued as COSV57651867; called by muse, mutect2
- FRAS1 | c.4309G>T p.V1437L | Missense Mutation (SNP) | VAF 24/156 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.687); catalogued as rs1560713046, COSV53629849; called by muse, mutect2, varscan2
- GK2 | c.1267C>A p.Q423K | Missense Mutation (SNP) | VAF 19/128 reads (15%) | SIFT tolerated (1); PolyPhen benign (0.034); catalogued as rs1053783159; called by muse, mutect2, varscan2
- HCN1 | c.2618C>A p.S873* | Nonsense Mutation (SNP) | VAF 134/695 reads (19%) | catalogued as COSV57528136; called by muse, mutect2, varscan2
- HDAC4 | c.3193G>T p.G1065C | Missense Mutation (SNP) | VAF 35/135 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.759); catalogued as COSV61870127; called by muse, mutect2, varscan2
- HMCN1 | c.298C>A p.P100T | Missense Mutation (SNP) | VAF 56/626 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1028100946, COSV54910202; called by muse, mutect2
- HMX1 | c.970C>T p.L324F | Missense Mutation (SNP) | VAF 11/42 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.046); catalogued as rs1295249726; called by muse, mutect2, varscan2
- HOXA2 | c.183del p.G62Afs*37 | Frame Shift Del (DEL) | VAF 107/528 reads (20%) | catalogued as COSV56065159; called by mutect2, pindel, varscan2
- HOXD9 | c.476G>A p.G159E | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.381); catalogued as rs1262799453; called by muse, mutect2, varscan2
- HRG | c.1298C>A p.P433Q | Missense Mutation (SNP) | VAF 39/253 reads (15%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.957); catalogued as COSV99215187; called by muse, mutect2, varscan2
- IGKV3-20 | c.185G>T p.G62V | Missense Mutation (SNP) | VAF 192/972 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); catalogued as rs1462344989; called by muse, mutect2, varscan2
- IGLV2-14 | c.232G>A p.G78R | Missense Mutation (SNP) | VAF 128/774 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as rs1367261901; called by muse, varscan2
- IMPG1 | c.68-1G>T p.X23_splice | Splice Site (SNP) | VAF 20/66 reads (30%) | catalogued as COSV100886361; called by muse, mutect2, varscan2
- INPP4A | c.2317C>T p.P773S (on ENST00000074304 / NM_001134224.1; = p.P734S on NM_001566.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 22/121 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV50786165; called by muse, mutect2, varscan2
- INSC | c.1292C>T p.T431M | Missense Mutation (SNP) | VAF 32/161 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as rs200762289; called by muse, mutect2, varscan2
- ITK | c.988C>A p.L330M | Missense Mutation (SNP) | VAF 135/794 reads (17%) | SIFT tolerated (0.45); PolyPhen possibly damaging (0.694); catalogued as COSV101439885; called by muse, mutect2, varscan2
- KCNH4 | c.1247C>T p.S416L | Missense Mutation (SNP) | VAF 39/155 reads (25%) | SIFT deleterious (0.04); PolyPhen benign (0.011); catalogued as rs773634955, COSV99237096; called by muse, mutect2, varscan2
- KIR3DL3 | c.1227C>A p.S409R | Missense Mutation (SNP) | VAF 104/342 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.02); catalogued as rs781440017; called by muse, mutect2, varscan2
- KRT79 | c.1312G>A p.A438T | Missense Mutation (SNP) | VAF 128/368 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs753377513; called by muse, mutect2, varscan2
- LCAT | c.301G>A p.D101N | Missense Mutation (SNP) | VAF 14/92 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs538148718, CM086845; called by muse, mutect2, varscan2
- LYPD3 | c.127G>A p.G43R | Missense Mutation (SNP) | VAF 61/284 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs772588419; called by muse, mutect2, varscan2
- MAEL | c.517G>T p.A173S | Missense Mutation (SNP) | VAF 36/259 reads (14%) | SIFT tolerated (0.22); PolyPhen benign (0.086); catalogued as COSV63306354; called by muse, mutect2, varscan2
- MAGEA6 | c.780G>T p.Q260H | Missense Mutation (SNP) | VAF 107/381 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.602); catalogued as rs1556836900; called by muse, mutect2, varscan2
- MBLAC1 | c.557C>T p.T186I | Missense Mutation (SNP) | VAF 32/184 reads (17%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.994); catalogued as rs760410447; called by muse, mutect2, varscan2
- METTL8 | c.418C>A p.R140S | Missense Mutation (SNP) | VAF 9/86 reads (10%) | SIFT tolerated (0.89); PolyPhen benign (0); catalogued as rs141169319, COSV104427544; called by mutect2, varscan2
- MFAP3 | c.622A>G p.I208V | Missense Mutation (SNP) | VAF 37/203 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs1162729962; called by muse, mutect2, varscan2
- MIB2 | c.1960G>A p.V654M | Missense Mutation (SNP) | VAF 50/341 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1419672697; called by muse, mutect2, varscan2
- MPDZ | c.931G>T p.A311S | Missense Mutation (SNP) | VAF 75/365 reads (21%) | SIFT tolerated (0.42); PolyPhen benign (0.015); catalogued as rs1450161161; called by muse, mutect2, varscan2
- MPP3 | c.339G>T p.K113N | Missense Mutation (SNP) | VAF 54/248 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV101263355; called by muse, mutect2, varscan2
- MRGPRD | c.101C>A p.A34D | Missense Mutation (SNP) | VAF 13/137 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.132); catalogued as COSV58423513; called by muse, mutect2, varscan2
- MXRA5 | c.7343C>G p.P2448R | Missense Mutation (SNP) | VAF 9/49 reads (18%) | SIFT tolerated (0.06); PolyPhen benign (0.288); catalogued as rs770867087; called by muse, mutect2, varscan2
- MYH4 | c.2134G>T p.G712C | Missense Mutation (SNP) | VAF 58/269 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99700997; called by muse, mutect2, varscan2
- NRG4 | c.206C>G p.A69G | Missense Mutation (SNP) | VAF 22/282 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.316); catalogued as COSV67529863; called by muse, mutect2
- NRXN1 | c.4311G>T p.E1437D | Missense Mutation (SNP) | VAF 77/340 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.015); catalogued as COSV100640265, COSV60499979; called by muse, mutect2, varscan2
- NYAP2 | c.1820A>G p.H607R | Missense Mutation (SNP) | VAF 40/146 reads (27%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.08); catalogued as rs1423961262; called by muse, mutect2, varscan2
- OR2T8 | c.841C>A p.P281T | Missense Mutation (SNP) | VAF 114/476 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100178458; called by muse, varscan2
- OR2W3 | c.174del p.M59Cfs*76 | Frame Shift Del (DEL) | VAF 42/278 reads (15%) | catalogued as COSV64456290; called by mutect2, pindel, varscan2
- OR56A4 | c.400C>A p.P134T | Missense Mutation (SNP) | VAF 12/118 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58110073; called by muse, mutect2
- OR5F1 | c.382C>A p.R128S | Missense Mutation (SNP) | VAF 16/88 reads (18%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as COSV53545058; called by mutect2, varscan2
- OR5T3 | c.103C>A p.L35M | Missense Mutation (SNP) | VAF 34/184 reads (18%) | SIFT tolerated (0.15); PolyPhen benign (0.115); catalogued as rs536035033; called by muse, mutect2, varscan2
- OTOG | c.4052G>A p.G1351E | Missense Mutation (SNP) | VAF 117/443 reads (26%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.819); catalogued as rs1459807941; called by muse, mutect2, varscan2
- PAPPA2 | c.319G>T p.V107F | Missense Mutation (SNP) | VAF 86/540 reads (16%) | SIFT tolerated, low confidence (0.41); PolyPhen benign (0); catalogued as COSV62785323; called by muse, mutect2, varscan2
- PDZD2 | c.3179C>T p.T1060M | Missense Mutation (SNP) | VAF 16/141 reads (11%) | SIFT tolerated (0.11); PolyPhen benign (0.003); catalogued as rs1245510302; called by muse, mutect2, varscan2
- PIK3R3 | c.125C>T p.P42L | Missense Mutation (SNP) | VAF 30/262 reads (11%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as COSV53111528; called by muse, mutect2, varscan2
- PIWIL2 | c.1456-1G>A p.X486_splice | Splice Site (SNP) | VAF 68/246 reads (28%) | catalogued as COSV63251516; called by muse, mutect2, varscan2
- PLPPR4 | c.1570A>G p.I524V | Missense Mutation (SNP) | VAF 53/262 reads (20%) | SIFT tolerated (0.19); PolyPhen benign (0.041); catalogued as rs766547999; called by muse, mutect2, varscan2
- PMFBP1 | c.498G>T p.L166F | Missense Mutation (SNP) | VAF 111/529 reads (21%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.998); catalogued as COSV52826613; called by muse, mutect2, varscan2
- PNLIP | c.1133G>A p.G378E | Missense Mutation (SNP) | VAF 13/150 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100981768; called by muse, mutect2
- POTEH | c.937C>A p.L313M | Missense Mutation (SNP) | VAF 60/1639 reads (4%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); catalogued as COSV100625179, COSV58883578, COSV58885617; called by muse, mutect2
- PRDM10 | c.1219C>T p.R407C | Missense Mutation (SNP) | VAF 57/301 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs771166298, COSV58805204; called by muse, mutect2, varscan2
- PRKCH | c.2048C>T p.P683L | Missense Mutation (SNP) | VAF 29/97 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as rs899676221; called by muse, mutect2, varscan2
- PRR5L | c.487C>G p.R163G | Missense Mutation (SNP) | VAF 24/414 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61121028; called by muse, mutect2
- RET | c.2374G>A p.G792R | Missense Mutation (SNP) | VAF 78/559 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs1289075493; called by muse, mutect2, varscan2
- RNF40 | c.465del p.P157Lfs*40 | Frame Shift Del (DEL) | VAF 51/169 reads (30%) | catalogued as COSV61216105; called by mutect2, pindel, varscan2
- RRP15 | c.504G>T p.R168S | Missense Mutation (SNP) | VAF 26/102 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV65117422; called by muse, mutect2, varscan2
- RTN1 | c.1268C>A p.A423E | Missense Mutation (SNP) | VAF 27/157 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.628); catalogued as COSV50718522; called by muse, mutect2, varscan2
- RYR2 | c.4829G>A p.R1610Q | Missense Mutation (SNP) | VAF 144/544 reads (26%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.805); catalogued as rs764687833, COSV63719217; ClinVar: uncertain significance; called by muse, varscan2
- RYR3 | c.944C>A p.S315Y | Missense Mutation (SNP) | VAF 28/227 reads (12%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.841); catalogued as COSV66780797; called by muse, mutect2, varscan2
- SALL3 | c.428G>A p.R143H | Missense Mutation (SNP) | VAF 7/40 reads (18%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as COSV73305998; called by muse, mutect2, varscan2
- SCART1 | c.3075G>T p.M1025I | Missense Mutation (SNP) | VAF 13/69 reads (19%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.018); catalogued as rs758710519; called by muse, mutect2, varscan2
- SCN10A | c.4774G>A p.G1592R | Missense Mutation (SNP) | VAF 123/464 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); catalogued as rs866103882, COSV71860409; called by muse, mutect2, varscan2
- SCN11A | c.3604G>T p.G1202* | Nonsense Mutation (SNP) | VAF 21/147 reads (14%) | catalogued as rs1553633786; called by muse, mutect2, varscan2
- SCN5A | c.2381T>C p.M794T | Missense Mutation (SNP) | VAF 34/104 reads (33%) | SIFT deleterious (0.02); PolyPhen benign (0.096); catalogued as rs1057520483; ClinVar: uncertain significance; called by muse, mutect2
- SEMG2 | c.1195T>C p.Y399H | Missense Mutation (SNP) | VAF 34/184 reads (18%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs879053121; called by muse, varscan2
- SLC29A3 | c.1202G>A p.R401H | Missense Mutation (SNP) | VAF 28/223 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.852); catalogued as rs199861210; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SLITRK3 | c.2645G>T p.S882I | Missense Mutation (SNP) | VAF 42/155 reads (27%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.015); catalogued as COSV53847218; called by muse, mutect2, varscan2
- SNCAIP | c.2099G>T p.R700M | Missense Mutation (SNP) | VAF 28/373 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); catalogued as COSV54403094, COSV54407852; called by muse, mutect2
- SPEN | c.3715A>C p.T1239P | Missense Mutation (SNP) | VAF 20/152 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); catalogued as rs1369148819; called by muse, mutect2, varscan2
- SPTA1 | c.4712G>C p.C1571S | Missense Mutation (SNP) | VAF 72/564 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs199899448, COSV100934170; called by muse, mutect2, varscan2
- TACC2 | c.2353G>T p.E785* | Nonsense Mutation (SNP) | VAF 33/172 reads (19%) | catalogued as COSV100554466, COSV57774056; called by muse, mutect2, varscan2
- TANC2 | c.5506G>T p.E1836* | Nonsense Mutation (SNP) | VAF 91/493 reads (18%) | catalogued as COSV67334469; called by muse, mutect2, varscan2
- TET2 | c.2143A>G p.N715D | Missense Mutation (SNP) | VAF 95/837 reads (11%) | SIFT tolerated (0.32); PolyPhen benign (0.003); catalogued as rs375016935; called by muse, mutect2, varscan2
- TRPC4 | c.2905C>A p.H969N (on ENST00000379705 / NM_016179.4; = p.H974N on NM_003306.3) | Missense Mutation (SNP) | VAF 19/74 reads (26%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.007); catalogued as COSV58992042; called by muse, mutect2, varscan2
- UBA6 | c.467G>A p.C156Y | Missense Mutation (SNP) | VAF 12/104 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs753948752; called by muse, mutect2, varscan2
- VPS13C | c.6020T>C p.I2007T (on ENST00000644861 / NM_020821.3; = p.I1964T on NM_017684.5) | Missense Mutation (SNP) | VAF 42/534 reads (8%) | SIFT deleterious (0.03); PolyPhen benign (0.15); catalogued as rs368291106; called by muse, mutect2
- WDR12 | c.1193G>A p.G398E | Missense Mutation (SNP) | VAF 18/334 reads (5%) | SIFT tolerated (0.9); PolyPhen benign (0.012); catalogued as COSV53687388; called by muse, mutect2
- WIPF1 | c.949G>T p.G317W | Missense Mutation (SNP) | VAF 49/152 reads (32%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as COSV99768882; called by muse, mutect2, varscan2
- ZFHX4 | c.3768C>G p.S1256R | Missense Mutation (SNP) | VAF 109/637 reads (17%) | SIFT tolerated (0.29); PolyPhen probably damaging (0.996); catalogued as COSV50802863; called by muse, mutect2, varscan2
- ZFP42 | c.134C>A p.A45E | Missense Mutation (SNP) | VAF 80/425 reads (19%) | SIFT tolerated (0.2); PolyPhen benign (0.018); catalogued as COSV58817504; called by muse, mutect2, varscan2
- ZFP62 | c.1387G>T p.G463C (on ENST00000502412 / NM_001377944.1; = p.G430C on NM_152283.5 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 52/395 reads (13%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.935); catalogued as rs1036403390; called by muse, mutect2, varscan2
- ZNF354B | c.98C>G p.P33R | Missense Mutation (SNP) | VAF 59/376 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.825); catalogued as COSV100483100; called by mutect2, varscan2
- ZNF804A | c.2678G>T p.G893V | Missense Mutation (SNP) | VAF 51/317 reads (16%) | SIFT tolerated (0.09); PolyPhen benign (0.033); catalogued as COSV56464298; called by muse, mutect2, varscan2
- ZNF862 | c.1126G>T p.A376S | Missense Mutation (SNP) | VAF 155/410 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.989); catalogued as rs368754892; called by muse, mutect2, varscan2
- A1CF | c.1287G>A p.M429I (on ENST00000373993 / NM_138932.2; = p.M421I on NM_014576.4) | Missense Mutation (SNP) | VAF 79/740 reads (11%) | SIFT tolerated (0.16); PolyPhen benign (0.23); called by muse, mutect2, varscan2
- ABCB1 | c.683C>A p.S228* | Nonsense Mutation (SNP) | VAF 265/722 reads (37%) | called by muse, mutect2, varscan2
- ACSBG1 | c.920G>T p.S307I | Missense Mutation (SNP) | VAF 9/121 reads (7%) | SIFT tolerated (0.1); PolyPhen benign (0.01); called by muse, mutect2
- ACTL6B | c.799T>A p.S267T | Missense Mutation (SNP) | VAF 108/311 reads (35%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.699); called by muse, mutect2, varscan2
- ADAM21 | c.1023T>A p.H341Q | Missense Mutation (SNP) | VAF 19/108 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ADAMTS13 | c.4028C>A p.A1343D | Missense Mutation (SNP) | VAF 30/374 reads (8%) | SIFT tolerated (0.17); PolyPhen benign (0.068); called by muse, mutect2
- ADAMTS17 | c.3253G>A p.A1085T | Missense Mutation (SNP) | VAF 124/434 reads (29%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.232); called by muse, mutect2, varscan2
- ADAMTS18 | c.90G>T p.K30N | Missense Mutation (SNP) | VAF 52/221 reads (24%) | SIFT tolerated, low confidence (0.08); PolyPhen possibly damaging (0.597); called by muse, mutect2, varscan2
- ADCY5 | c.3116T>A p.L1039Q | Missense Mutation (SNP) | VAF 38/169 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.945); called by muse, mutect2, varscan2
- ADGRL3 | c.3857C>A p.P1286Q | Missense Mutation (SNP) | VAF 37/212 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- ADHFE1 | c.1271G>T p.G424V | Missense Mutation (SNP) | VAF 15/98 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ALKBH8 | c.1784C>T p.P595L | Missense Mutation (SNP) | VAF 9/88 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- AMER3 | c.2518G>T p.E840* | Nonsense Mutation (SNP) | VAF 27/152 reads (18%) | called by muse, mutect2, varscan2
- ANO4 | c.2431C>G p.Q811E (on ENST00000392977 / NM_001286615.2; = p.Q776E on NM_178826.4) | Missense Mutation (SNP) | VAF 29/67 reads (43%) | SIFT tolerated (0.68); PolyPhen benign (0.044); called by muse, mutect2, varscan2
- AOX1 | c.320C>A p.A107D | Missense Mutation (SNP) | VAF 32/150 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- AP4E1 | c.853G>C p.G285R | Missense Mutation (SNP) | VAF 40/170 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- AP5B1 | c.1687G>A p.A563T | Missense Mutation (SNP) | VAF 45/190 reads (24%) | SIFT tolerated (0.16); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- ASH1L | c.7569G>T p.E2523D (on ENST00000368346 / NM_001366177.2; = p.E2518D on NM_018489.3) | Missense Mutation (SNP) | VAF 12/62 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.965); called by muse, mutect2, varscan2
- ATP6V1C1 | c.474-1G>T p.X158_splice | Splice Site (SNP) | VAF 32/123 reads (26%) | called by muse, mutect2, varscan2
- BAZ2B | c.1136G>T p.G379V | Missense Mutation (SNP) | VAF 87/425 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- C12orf50 | c.280G>T p.E94* | Nonsense Mutation (SNP) | VAF 49/104 reads (47%) | called by muse, mutect2, varscan2
- C1QTNF4 | c.383A>T p.Y128F | Missense Mutation (SNP) | VAF 9/55 reads (16%) | SIFT tolerated (0.68); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- C6 | c.359C>A p.P120H | Missense Mutation (SNP) | VAF 57/380 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.827); called by muse, mutect2, varscan2
- C9 | c.233G>C p.C78S | Missense Mutation (SNP) | VAF 62/437 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); called by muse, mutect2, varscan2
- CACNA2D1 | c.888C>A p.S296R | Missense Mutation (SNP) | VAF 75/232 reads (32%) | SIFT deleterious (0.04); PolyPhen benign (0.21); called by muse, mutect2, varscan2
- CACTIN | c.1114G>T p.D372Y | Missense Mutation (SNP) | VAF 54/219 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CALCB | c.299C>A p.S100* | Nonsense Mutation (SNP) | VAF 139/475 reads (29%) | called by muse, mutect2, varscan2
- CAP2 | c.1003-1G>A p.X335_splice | Splice Site (SNP) | VAF 7/112 reads (6%) | called by muse, mutect2
- CAPN7 | c.1675C>T p.P559S | Missense Mutation (SNP) | VAF 70/255 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); called by muse, mutect2, varscan2
- CARNS1 | c.896C>A p.A299E | Missense Mutation (SNP) | VAF 3/24 reads (13%) | SIFT tolerated (0.06); PolyPhen benign (0.062); called by muse, mutect2
- CCDC102A | c.208G>C p.E70Q | Missense Mutation (SNP) | VAF 15/88 reads (17%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- CCDC166 | c.1205del p.G402Afs*25 | Frame Shift Del (DEL) | VAF 23/220 reads (10%) | called by mutect2, pindel, varscan2
- CCDC168 | c.12617A>T p.E4206V | Missense Mutation (SNP) | VAF 31/115 reads (27%) | SIFT tolerated (0.29); PolyPhen benign (0.167); called by muse, mutect2, varscan2
- CCNY | c.979G>T p.A327S | Missense Mutation (SNP) | VAF 82/395 reads (21%) | SIFT tolerated (0.27); PolyPhen benign (0.371); called by muse, mutect2, varscan2
- CD1E | c.544C>A p.L182M | Missense Mutation (SNP) | VAF 68/435 reads (16%) | SIFT deleterious (0.04); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- CDCA7 | c.545G>T p.R182M (on ENST00000347703 / NM_145810.3; = p.R261M on NM_031942.5) | Missense Mutation (SNP) | VAF 53/268 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- CDSN | c.853C>A p.P285T | Missense Mutation (SNP) | VAF 149/308 reads (48%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CES1 | c.497T>C p.V166A | Missense Mutation (SNP) | VAF 139/1110 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- CHD7 | c.2176G>A p.D726N | Missense Mutation (SNP) | VAF 21/336 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.681); called by muse, mutect2
- CHST1 | c.542G>T p.C181F | Missense Mutation (SNP) | VAF 43/159 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); called by muse, mutect2, varscan2
- CLCN1 | c.2845G>A p.G949S | Missense Mutation (SNP) | VAF 8/60 reads (13%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CNTNAP2 | c.16C>G p.R6G | Missense Mutation (SNP) | VAF 20/172 reads (12%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0); called by muse, mutect2, varscan2
- CNTNAP2 | c.1945C>A p.P649T | Missense Mutation (SNP) | VAF 237/663 reads (36%) | SIFT tolerated (0.4); PolyPhen benign (0); called by muse, mutect2, varscan2
- COL1A2 | c.3947G>T p.G1316V | Missense Mutation (SNP) | VAF 167/511 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- COL22A1 | c.4013C>A p.P1338H | Missense Mutation (SNP) | VAF 47/333 reads (14%) | SIFT deleterious (0.03); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- COL22A1 | c.1285C>T p.H429Y | Missense Mutation (SNP) | VAF 68/420 reads (16%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.715); called by muse, mutect2, varscan2
- COL3A1 | c.412C>A p.P138T | Missense Mutation (SNP) | VAF 71/426 reads (17%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.947); called by muse, mutect2, varscan2
- COL6A5 | c.2848G>T p.A950S | Missense Mutation (SNP) | VAF 174/754 reads (23%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- CORIN | c.2239G>A p.E747K | Missense Mutation (SNP) | VAF 61/350 reads (17%) | SIFT tolerated (0.92); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CPZ | c.117C>G p.D39E | Missense Mutation (SNP) | VAF 30/187 reads (16%) | SIFT tolerated, low confidence (0.86); PolyPhen benign (0); called by muse, mutect2, varscan2
- CR1L | c.508A>T p.T170S | Missense Mutation (SNP) | VAF 84/499 reads (17%) | SIFT tolerated (0.31); PolyPhen benign (0.235); called by muse, mutect2, varscan2
- CSMD3 | c.8736G>T p.K2912N (on ENST00000297405 / NM_001363185.1; = p.K2743N on NM_052900.3) | Missense Mutation (SNP) | VAF 103/377 reads (27%) | SIFT tolerated (0.05); PolyPhen benign (0.232); called by muse, mutect2, varscan2
- CXCL6 | c.47G>T p.G16V | Missense Mutation (SNP) | VAF 73/399 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- CYB5A | c.260A>T p.D87V | Missense Mutation (SNP) | VAF 47/432 reads (11%) | SIFT tolerated (0.09); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- DBN1 | c.917G>C p.G306A | Missense Mutation (SNP) | VAF 75/374 reads (20%) | SIFT tolerated (0.16); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- DCAF4L2 | c.1144C>T p.L382F | Missense Mutation (SNP) | VAF 12/60 reads (20%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.999); called by muse, mutect2
- DENND2B | c.220G>A p.A74T | Missense Mutation (SNP) | VAF 12/61 reads (20%) | SIFT tolerated, low confidence (0.69); PolyPhen benign (0); called by muse, mutect2
- DGKB | c.2001G>T p.M667I | Missense Mutation (SNP) | VAF 26/172 reads (15%) | SIFT tolerated (0.22); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- DHX35 | c.349G>A p.A117T | Missense Mutation (SNP) | VAF 70/308 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- DISP1 | c.354G>C p.Q118H | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT tolerated (0.06); PolyPhen benign (0.212); called by muse, mutect2, varscan2
- DLG5 | c.1492C>T p.L498F | Missense Mutation (SNP) | VAF 31/208 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- DLGAP2 | c.1052G>T p.C351F | Missense Mutation (SNP) | VAF 51/189 reads (27%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- DMGDH | c.682G>T p.G228* | Nonsense Mutation (SNP) | VAF 147/703 reads (21%) | called by muse, mutect2, varscan2
- DOCK10 | c.900G>T p.R300S | Missense Mutation (SNP) | VAF 48/207 reads (23%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.784); called by muse, mutect2, varscan2
- DOCK10 | c.899G>T p.R300M | Missense Mutation (SNP) | VAF 48/213 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); called by muse, mutect2, varscan2
- DPP9 | c.1942C>T p.Q648* (on ENST00000598800; = p.Q677* on NM_139159.5) | Nonsense Mutation (SNP) | VAF 12/88 reads (14%) | called by muse, mutect2, varscan2
- DST | c.6763G>T p.A2255S | Missense Mutation (SNP) | VAF 55/179 reads (31%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0); called by muse, mutect2, varscan2
- E2F2 | c.1201A>T p.I401F | Missense Mutation (SNP) | VAF 28/174 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.601); called by muse, mutect2, varscan2
- EIF3A | c.3037G>A p.D1013N | Missense Mutation (SNP) | VAF 128/598 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.033); called by muse, mutect2, varscan2
- EXOC3L4 | c.540G>T p.M180I | Missense Mutation (SNP) | VAF 51/220 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.874); called by muse, mutect2, varscan2
- FAM20A | c.1130A>T p.Y377F | Missense Mutation (SNP) | VAF 86/412 reads (21%) | SIFT tolerated (0.08); PolyPhen benign (0.272); called by muse, mutect2, varscan2
- FAM90A26 | c.101del p.P34Rfs*28 | Frame Shift Del (DEL) | VAF 59/163 reads (36%) | called by mutect2, pindel, varscan2
- FBXL7 | c.1133T>A p.L378Q | Missense Mutation (SNP) | VAF 28/110 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- FCRL2 | c.1044dup p.G349Wfs*21 | Frame Shift Ins (INS) | VAF 76/250 reads (30%) | called by mutect2, varscan2
- FCRL2 | c.1043delinsAT p.S348Yfs*22 | Frame Shift Ins (INS) | VAF 29/278 reads (10%) | called by mutect2*, pindel, varscan2*
- FER1L5 | c.86-2A>T p.X29_splice | Splice Site (SNP) | VAF 43/224 reads (19%) | called by muse, mutect2, varscan2
- FER1L6 | c.2039G>C p.G680A | Missense Mutation (SNP) | VAF 15/146 reads (10%) | SIFT tolerated (0.96); PolyPhen benign (0.001); called by muse, mutect2
- FGF1 | c.381delinsAA p.N129Efs*27 | Frame Shift Ins (INS) | VAF 65/568 reads (11%) | called by pindel, varscan2*
- FLG | c.5497del p.V1833* | Frame Shift Del (DEL) | VAF 68/411 reads (17%) | called by mutect2, pindel, varscan2
- FLG2 | c.5149G>A p.G1717R | Missense Mutation (SNP) | VAF 37/402 reads (9%) | SIFT tolerated (0.05); PolyPhen benign (0.201); called by muse, mutect2
- FLT4 | c.1018G>A p.G340R | Missense Mutation (SNP) | VAF 93/414 reads (22%) | SIFT tolerated (0.07); PolyPhen benign (0.15); called by muse, mutect2, varscan2
- FMN2 | c.2088G>T p.Q696H | Missense Mutation (SNP) | VAF 90/458 reads (20%) | SIFT deleterious (0.03); PolyPhen benign (0.071); called by muse, mutect2, varscan2
- FMN2 | c.3766A>T p.T1256S | Missense Mutation (SNP) | VAF 67/209 reads (32%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- FRMPD3 | c.3106G>T p.A1036S | Missense Mutation (SNP) | VAF 58/191 reads (30%) | SIFT tolerated, low confidence (0.87); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- FSIP2 | c.6374A>T p.K2125I | Missense Mutation (SNP) | VAF 40/212 reads (19%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.85); called by muse, mutect2, varscan2
- GABRG3 | c.637C>A p.Q213K | Missense Mutation (SNP) | VAF 89/423 reads (21%) | SIFT tolerated (0.61); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- GCM1 | c.67C>G p.L23V | Missense Mutation (SNP) | VAF 147/373 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- GEMIN6 | c.98G>T p.W33L | Missense Mutation (SNP) | VAF 20/155 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- GGT7 | c.1780G>T p.G594C | Missense Mutation (SNP) | VAF 56/300 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.954); called by muse, mutect2, varscan2
- GIMAP1-GIMAP5 | c.464C>T p.S155F | Missense Mutation (SNP) | VAF 114/825 reads (14%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.187); called by muse, mutect2, varscan2
- GIP | c.140C>G p.P47R | Missense Mutation (SNP) | VAF 36/190 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.832); called by muse, mutect2, varscan2
- GPR148 | c.1043A>G p.*348Wext*3 | Nonstop Mutation (SNP) | VAF 55/244 reads (23%) | called by muse, mutect2, varscan2
- GPR161 | c.440C>A p.A147E | Missense Mutation (SNP) | VAF 28/143 reads (20%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.659); called by muse, mutect2, varscan2
- HCN1 | c.2116C>A p.P706T | Missense Mutation (SNP) | VAF 16/72 reads (22%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.052); called by muse, mutect2, varscan2
- HEATR5A | c.4292G>C p.G1431A | Missense Mutation (SNP) | VAF 40/366 reads (11%) | SIFT tolerated (0.5); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- HECW1 | c.1722G>T p.Q574H | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.424); called by muse, mutect2, varscan2
- HERC1 | c.10973del p.G3658Dfs*15 | Frame Shift Del (DEL) | VAF 49/300 reads (16%) | called by mutect2, pindel, varscan2
- HERC1 | c.9171-1G>T p.X3057_splice | Splice Site (SNP) | VAF 32/286 reads (11%) | called by muse, mutect2, varscan2
- HIPK3 | c.2839G>T p.D947Y | Missense Mutation (SNP) | VAF 40/258 reads (16%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.855); called by muse, varscan2
- HTR3C | c.560T>A p.V187E | Missense Mutation (SNP) | VAF 14/38 reads (37%) | SIFT deleterious (0.04); PolyPhen benign (0.081); called by mutect2, varscan2
- HYDIN | c.2075G>T p.R692M | Missense Mutation (SNP) | VAF 24/124 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- IGHV1-58 | c.188G>T p.R63L | Missense Mutation (SNP) | VAF 151/716 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- IGKV1-27 | c.89C>A p.P30Q | Missense Mutation (SNP) | VAF 69/662 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- IGKV1-6 | c.175C>A p.Q59K | Missense Mutation (SNP) | VAF 176/869 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.833); called by muse, mutect2, varscan2
- IGKV1-9 | c.16C>G p.P6A | Missense Mutation (SNP) | VAF 83/581 reads (14%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.165); called by muse, mutect2, varscan2
- IGKV3D-15 | c.7G>T p.A3S | Missense Mutation (SNP) | VAF 58/535 reads (11%) | SIFT tolerated (1); PolyPhen benign (0.022); called by muse, mutect2, varscan2
- INO80C | c.208A>T p.S70C | Missense Mutation (SNP) | VAF 120/468 reads (26%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.541); called by muse, mutect2, varscan2
- IREB2 | c.2653G>T p.G885* | Nonsense Mutation (SNP) | VAF 26/254 reads (10%) | called by muse, mutect2, varscan2
- ISLR | c.1182del p.N395Tfs*78 | Frame Shift Del (DEL) | VAF 8/84 reads (10%) | called by mutect2, pindel
- ITGA11 | c.1393C>A p.L465I | Missense Mutation (SNP) | VAF 64/352 reads (18%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.804); called by muse, mutect2, varscan2
- ITPRID1 | c.2998C>G p.Q1000E | Missense Mutation (SNP) | VAF 82/558 reads (15%) | SIFT tolerated (0.09); PolyPhen benign (0.116); called by muse, mutect2, varscan2
- JAG2 | c.1399G>C p.G467R | Missense Mutation (SNP) | VAF 67/384 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- KALRN | c.627G>T p.E209D | Missense Mutation (SNP) | VAF 179/673 reads (27%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- KANK4 | c.2589G>T p.M863I | Missense Mutation (SNP) | VAF 18/139 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- KCNA4 | c.691A>C p.I231L | Missense Mutation (SNP) | VAF 53/189 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- KCNB2 | c.1375G>T p.A459S | Missense Mutation (SNP) | VAF 32/212 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.347); called by muse, mutect2, varscan2
- KDM4A | c.694C>T p.Q232* | Nonsense Mutation (SNP) | VAF 20/242 reads (8%) | called by muse, mutect2
- KIAA1109 | c.14579A>C p.E4860A | Missense Mutation (SNP) | VAF 39/319 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- KIAA2013 | c.1189G>A p.E397K | Missense Mutation (SNP) | VAF 21/79 reads (27%) | SIFT tolerated (0.15); PolyPhen benign (0.124); called by muse, mutect2, varscan2
- KIF27 | c.906del p.D304Ifs*11 | Frame Shift Del (DEL) | VAF 26/121 reads (21%) | called by mutect2, pindel, varscan2
- KLK2 | c.188C>G p.A63G | Missense Mutation (SNP) | VAF 10/76 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- KNG1 | c.1037G>T p.G346V | Missense Mutation (SNP) | VAF 106/657 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- L3MBTL1 | c.413del p.P138Rfs*10 (on ENST00000418998 / NM_001377303.1; = p.P48Rfs*10 on NM_015478.7) | Frame Shift Del (DEL) | VAF 32/194 reads (16%) | called by mutect2, pindel, varscan2
- LAT | c.614A>G p.E205G | Missense Mutation (SNP) | VAF 10/54 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.923); called by muse, varscan2
- LCE3E | c.67C>A p.P23T | Missense Mutation (SNP) | VAF 151/424 reads (36%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.349); called by muse, mutect2, varscan2
- LCK | c.761G>C p.G254A | Missense Mutation (SNP) | VAF 16/50 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); called by muse, mutect2, varscan2
- LHCGR | c.1933A>G p.K645E | Missense Mutation (SNP) | VAF 108/503 reads (21%) | SIFT tolerated (0.92); PolyPhen benign (0.183); called by muse, mutect2, varscan2
- LRRC9 | c.1797T>A p.S599R | Missense Mutation (SNP) | VAF 57/286 reads (20%) | SIFT tolerated (0.06); PolyPhen benign (0.403); called by muse, mutect2, varscan2
- LTB4R2 | c.221G>A p.W74* (on ENST00000528054; = p.W43* on NM_019839.5) | Nonsense Mutation (SNP) | VAF 21/88 reads (24%) | called by muse, mutect2, varscan2
- LTN1 | c.2124G>T p.V708= | Splice Region (SNP) | VAF 6/92 reads (7%) | called by muse, mutect2
- LY6H | c.378del p.L127Sfs*24 | Frame Shift Del (DEL) | VAF 26/144 reads (18%) | called by mutect2, pindel, varscan2
- MAP2 | c.2118G>A p.M706I | Missense Mutation (SNP) | VAF 37/175 reads (21%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- MAP2K3 | c.526G>T p.A176S (on ENST00000342679 / NM_145109.3; = p.A147S on NM_002756.4) | Missense Mutation (SNP) | VAF 30/356 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- METTL15 | c.767G>A p.S256N | Missense Mutation (SNP) | VAF 52/175 reads (30%) | SIFT tolerated (0.13); PolyPhen benign (0.044); called by muse, mutect2
- MICA | c.667G>T p.V223L | Missense Mutation (SNP) | VAF 29/106 reads (27%) | SIFT tolerated (1); PolyPhen benign (0.166); called by muse, mutect2
- MICB | c.667G>T p.V223L | Missense Mutation (SNP) | VAF 35/202 reads (17%) | SIFT tolerated (1); PolyPhen benign (0.024); called by muse, varscan2
- MROH1 | c.3017G>T p.R1006L | Missense Mutation (SNP) | VAF 27/194 reads (14%) | SIFT tolerated (0.35); PolyPhen benign (0.056); called by muse, mutect2, varscan2
- MS4A1 | c.107C>A p.S36* | Nonsense Mutation (SNP) | VAF 53/226 reads (23%) | called by muse, mutect2, varscan2
- MTR | c.3509G>T p.G1170V | Missense Mutation (SNP) | VAF 60/318 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- MUC16 | c.27845C>A p.S9282* | Nonsense Mutation (SNP) | VAF 23/61 reads (38%) | called by muse, mutect2, varscan2
- MYH11 | c.1304G>C p.W435S | Missense Mutation (SNP) | VAF 61/271 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- MYH4 | c.5536A>G p.K1846E | Missense Mutation (SNP) | VAF 64/293 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); called by muse, mutect2, varscan2
- MYO19 | c.1611del p.Y538Tfs*18 | Frame Shift Del (DEL) | VAF 22/117 reads (19%) | called by mutect2, pindel, varscan2
- MYT1 | c.87C>G p.S29R | Missense Mutation (SNP) | VAF 39/235 reads (17%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- MYT1 | c.3143T>A p.L1048H | Missense Mutation (SNP) | VAF 31/244 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.063); called by muse, mutect2, varscan2
- NAV3 | c.6980C>A p.T2327N (on ENST00000397909 / NM_001024383.2; = p.T2305N on NM_014903.6) | Missense Mutation (SNP) | VAF 112/407 reads (28%) | SIFT tolerated (0.05); PolyPhen benign (0.046); called by muse, mutect2, varscan2
- NCOA2 | c.3379G>T p.E1127* | Nonsense Mutation (SNP) | VAF 50/240 reads (21%) | called by muse, mutect2, varscan2
- NDST3 | c.1947T>A p.Y649* | Nonsense Mutation (SNP) | VAF 12/84 reads (14%) | called by muse, mutect2
- NLRP10 | c.138A>C p.R46S | Missense Mutation (SNP) | VAF 77/534 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- NLRP3 | c.1358G>T p.G453V | Missense Mutation (SNP) | VAF 25/144 reads (17%) | SIFT tolerated (0.14); PolyPhen benign (0.066); called by muse, mutect2, varscan2
- NPAS3 | c.247G>T p.A83S (on ENST00000356141 / NM_001164749.2; = p.A53S on NM_022123.3) | Missense Mutation (SNP) | VAF 145/730 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.809); called by muse, mutect2, varscan2
- NPIPB9 | c.56G>T p.R19M | Missense Mutation (SNP) | VAF 24/120 reads (20%) | SIFT deleterious, low confidence (0); called by mutect2, varscan2
- NRCAM | c.3340G>T p.V1114L | Missense Mutation (SNP) | VAF 39/288 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- NT5DC3 | c.1475G>C p.R492P | Missense Mutation (SNP) | VAF 130/390 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- NUTM2G | c.1577C>A p.P526H | Missense Mutation (SNP) | VAF 52/233 reads (22%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.647); called by muse, mutect2, varscan2
- NXPE2 | c.422A>G p.H141R | Missense Mutation (SNP) | VAF 27/185 reads (15%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- OLFML2A | c.1789C>A p.Q597K | Missense Mutation (SNP) | VAF 94/237 reads (40%) | SIFT tolerated (0.15); PolyPhen benign (0.078); called by muse, mutect2, varscan2
- OMA1 | c.171G>C p.Q57H | Missense Mutation (SNP) | VAF 32/286 reads (11%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- OR1J2 | c.119dup p.N42Efs*29 | Frame Shift Ins (INS) | VAF 76/309 reads (25%) | called by mutect2, pindel, varscan2
- OR1M1 | c.284C>T p.P95L | Missense Mutation (SNP) | VAF 65/225 reads (29%) | SIFT tolerated (0.1); PolyPhen benign (0); called by muse, mutect2, varscan2
- OR2G2 | c.289T>C p.Y97H | Missense Mutation (SNP) | VAF 47/238 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.26); called by muse, mutect2, varscan2
- OR52J3 | c.314T>C p.L105P | Missense Mutation (SNP) | VAF 75/277 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); called by muse, mutect2, varscan2
- OTOG | c.8268C>A p.C2756* | Nonsense Mutation (SNP) | VAF 40/255 reads (16%) | called by muse, mutect2, varscan2
- P4HA1 | c.186G>T p.K62N | Missense Mutation (SNP) | VAF 26/114 reads (23%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.944); called by muse, mutect2, varscan2
- PARD3B | c.2423G>T p.G808V (on ENST00000406610 / NM_001302769.2; = p.G739V on NM_057177.7) | Missense Mutation (SNP) | VAF 25/112 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- PBRM1 | c.1630del p.D544Tfs*25 | Frame Shift Del (DEL) | VAF 27/190 reads (14%) | called by mutect2, pindel, varscan2
- PCDH11X | c.1173C>A p.D391E | Missense Mutation (SNP) | VAF 110/462 reads (24%) | SIFT tolerated (0.19); PolyPhen benign (0.116); called by muse, mutect2, varscan2
- PCDHB9 | c.1639G>T p.V547L | Missense Mutation (SNP) | VAF 149/781 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.159); called by muse, mutect2, varscan2
- PCDHGA4 | c.1538G>T p.G513V | Missense Mutation (SNP) | VAF 32/156 reads (21%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- PEAR1 | c.387C>A p.D129E | Missense Mutation (SNP) | VAF 41/269 reads (15%) | SIFT tolerated (0.6); PolyPhen possibly damaging (0.674); called by muse, mutect2, varscan2
- PHF11 | c.987_991del p.S330Lfs*7 | Frame Shift Del (DEL) | VAF 9/61 reads (15%) | called by mutect2, pindel, varscan2
- PLCB2 | c.231G>A p.K77= | Splice Region (SNP) | VAF 36/182 reads (20%) | called by muse, mutect2, varscan2
- PLD4 | c.4C>A p.L2M | Missense Mutation (SNP) | VAF 14/62 reads (23%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.146); called by muse, mutect2, varscan2
- PLD5 | c.1077C>A p.Y359* (on ENST00000442594; = p.Y297* on NM_001195811.1 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 7/67 reads (10%) | called by muse, mutect2
- PLXNB1 | c.4970G>T p.R1657L | Missense Mutation (SNP) | VAF 55/205 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.763); called by muse, mutect2, varscan2
- POLQ | c.1649T>A p.M550K | Missense Mutation (SNP) | VAF 56/279 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.028); called by muse, mutect2, varscan2
- POT1 | c.851A>T p.D284V | Missense Mutation (SNP) | VAF 76/198 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.841); called by muse, mutect2, varscan2
- PRG4 | c.3G>T p.M1? | Translation Start Site (SNP) | VAF 46/361 reads (13%) | SIFT tolerated (0.25); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- PRRX2 | c.361C>A p.R121S | Missense Mutation (SNP) | VAF 45/152 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.895); called by muse, mutect2, varscan2
- PRSS58 | c.554C>A p.P185Q | Missense Mutation (SNP) | VAF 63/349 reads (18%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.912); called by muse, mutect2, varscan2
- PTP4A3 | c.230C>T p.P77L | Missense Mutation (SNP) | VAF 14/287 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.906); called by muse, mutect2
- PTPRB | c.4928G>T p.R1643I | Missense Mutation (SNP) | VAF 131/325 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- PUS1 | c.1167G>T p.Q389H | Missense Mutation (SNP) | VAF 153/423 reads (36%) | SIFT tolerated (0.07); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- RAB3GAP1 | c.833A>T p.E278V | Missense Mutation (SNP) | VAF 32/238 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- RGS4 | c.379G>T p.V127L | Missense Mutation (SNP) | VAF 27/165 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.858); called by muse, mutect2, varscan2
- RIMS4 | c.300G>T p.M100I | Missense Mutation (SNP) | VAF 56/225 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- RPL5 | c.716T>C p.M239T | Missense Mutation (SNP) | VAF 14/272 reads (5%) | SIFT tolerated (0.05); PolyPhen benign (0.018); called by muse, mutect2
- RPS6KA2 | c.427G>T p.G143* | Nonsense Mutation (SNP) | VAF 39/175 reads (22%) | called by muse, mutect2, varscan2
- RSPH4A | c.1305T>A p.N435K | Missense Mutation (SNP) | VAF 75/276 reads (27%) | SIFT deleterious (0.05); PolyPhen benign (0.056); called by muse, mutect2, varscan2
- SAMD9 | c.1253A>T p.N418I | Missense Mutation (SNP) | VAF 14/80 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- SCN2A | c.5687T>A p.I1896N | Missense Mutation (SNP) | VAF 152/702 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- SDAD1 | c.921T>A p.C307* | Nonsense Mutation (SNP) | VAF 34/198 reads (17%) | called by muse, mutect2, varscan2
- SEC63 | c.2034G>T p.E678D | Missense Mutation (SNP) | VAF 28/177 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.962); called by muse, mutect2, varscan2
- SELENOI | c.713G>C p.S238T | Missense Mutation (SNP) | VAF 22/118 reads (19%) | SIFT tolerated (0.8); PolyPhen benign (0.116); called by muse, mutect2
- SEMA5A | c.1904T>G p.V635G | Missense Mutation (SNP) | VAF 32/159 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SLC26A3 | c.384T>C p.G128= | Splice Region (SNP) | VAF 75/569 reads (13%) | called by muse, mutect2, varscan2
- SLC36A2 | c.797C>T p.P266L | Missense Mutation (SNP) | VAF 124/614 reads (20%) | SIFT tolerated (0.24); PolyPhen benign (0.25); called by muse, mutect2, varscan2
- SLC8A1 | c.980C>T p.A327V | Missense Mutation (SNP) | VAF 56/459 reads (12%) | SIFT tolerated (0.27); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- SLC8A2 | c.485del p.P162Qfs*34 | Frame Shift Del (DEL) | VAF 38/145 reads (26%) | called by mutect2, pindel, varscan2
- SOGA1 | c.1798A>C p.N600H | Missense Mutation (SNP) | VAF 42/218 reads (19%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SORCS1 | c.2059-2A>T p.X687_splice | Splice Site (SNP) | VAF 16/89 reads (18%) | called by muse, mutect2, varscan2
- SORCS3 | c.1564A>T p.R522W | Missense Mutation (SNP) | VAF 50/398 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- SPDYE6 | c.917T>A p.I306K | Missense Mutation (SNP) | VAF 195/2323 reads (8%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.011); called by muse, mutect2
- SPTA1 | c.5347G>T p.A1783S | Missense Mutation (SNP) | VAF 117/907 reads (13%) | SIFT tolerated (0.89); PolyPhen benign (0.042); called by mutect2, varscan2
- SRRM2 | c.3226G>A p.V1076M | Missense Mutation (SNP) | VAF 50/255 reads (20%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0); called by muse, mutect2, varscan2
- SV2A | c.1955T>C p.I652T | Missense Mutation (SNP) | VAF 79/599 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.747); called by muse, mutect2, varscan2
- SYTL5 | c.327del p.I109Mfs*4 | Frame Shift Del (DEL) | VAF 12/108 reads (11%) | called by mutect2, pindel
- TBX5 | c.454C>A p.L152I | Missense Mutation (SNP) | VAF 144/476 reads (30%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.535); called by muse, mutect2, varscan2
- TENM2 | c.5636C>A p.P1879H (on ENST00000518659 / NM_001122679.2; = p.P1640H on NM_001080428.3) | Missense Mutation (SNP) | VAF 12/127 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- TET3 | c.1790C>T p.P597L | Missense Mutation (SNP) | VAF 27/250 reads (11%) | SIFT tolerated (0.36); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- TF | c.428G>T p.R143M | Missense Mutation (SNP) | VAF 51/249 reads (20%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.809); called by muse, mutect2, varscan2
- TFAP2D | c.932A>T p.E311V | Missense Mutation (SNP) | VAF 145/332 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); called by muse, mutect2, varscan2
- TG | c.3555G>T p.Q1185H | Missense Mutation (SNP) | VAF 57/277 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.819); called by muse, mutect2, varscan2
- TMCC2 | c.556A>T p.S186C | Missense Mutation (SNP) | VAF 26/126 reads (21%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.334); called by muse, mutect2, varscan2
- TNNI1 | c.559C>A p.Q187K | Missense Mutation (SNP) | VAF 59/291 reads (20%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.678); called by muse, mutect2, varscan2
- TOPBP1 | c.1929G>T p.M643I | Missense Mutation (SNP) | VAF 26/256 reads (10%) | SIFT tolerated (0.4); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- TRBV4-2 | c.320T>A p.L107Q | Missense Mutation (SNP) | VAF 18/81 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); called by muse, mutect2, varscan2
- TRDN | c.291G>T p.E97D | Missense Mutation (SNP) | VAF 27/128 reads (21%) | SIFT tolerated, low confidence (0.06); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- TRIM6 | c.854G>C p.R285T | Missense Mutation (SNP) | VAF 42/581 reads (7%) | SIFT tolerated (0.15); PolyPhen benign (0.006); called by muse, mutect2
- TRUB1 | c.466G>T p.G156W | Missense Mutation (SNP) | VAF 89/400 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TSHZ1 | c.359A>T p.Y120F (on ENST00000580243 / NM_001308210.2; = p.Y75F on NM_005786.6) | Missense Mutation (SNP) | VAF 16/74 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2
- TSHZ1 | c.361G>T p.A121S (on ENST00000580243 / NM_001308210.2; = p.A76S on NM_005786.6) | Missense Mutation (SNP) | VAF 17/74 reads (23%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.505); called by muse, mutect2
- TSHZ1 | c.805G>T p.G269C (on ENST00000580243 / NM_001308210.2; = p.G224C on NM_005786.6) | Missense Mutation (SNP) | VAF 25/148 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TTC21B | c.2168G>T p.R723L | Missense Mutation (SNP) | VAF 51/346 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.209); called by muse, mutect2, varscan2
- TTC24 | c.933G>T p.E311D | Missense Mutation (SNP) | VAF 33/257 reads (13%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.877); called by muse, mutect2, varscan2
- TTN | c.82988C>G p.A27663G (on ENST00000591111; = p.A20239G on NM_003319.4) | Missense Mutation (SNP) | VAF 170/912 reads (19%) | PolyPhen possibly damaging (0.861); called by muse, mutect2, varscan2
- TWSG1 | c.375A>C p.E125D | Missense Mutation (SNP) | VAF 104/404 reads (26%) | SIFT tolerated (0.19); PolyPhen benign (0.054); called by muse, mutect2, varscan2
- UGT2A3 | c.237G>C p.M79I | Missense Mutation (SNP) | VAF 33/265 reads (12%) | SIFT tolerated (0.1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- UGT2B11 | c.1485del p.L497Cfs*8 | Frame Shift Del (DEL) | VAF 118/734 reads (16%) | called by mutect2, pindel, varscan2
- UGT2B4 | c.526C>A p.P176T | Missense Mutation (SNP) | VAF 13/77 reads (17%) | SIFT tolerated (0.2); PolyPhen benign (0.371); called by muse, mutect2, varscan2
- USH2A | c.4792C>A p.H1598N | Missense Mutation (SNP) | VAF 26/153 reads (17%) | SIFT tolerated (0.41); PolyPhen benign (0); called by muse, mutect2, varscan2
- USP40 | c.628G>A p.E210K | Missense Mutation (SNP) | VAF 25/340 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2
- VCAM1 | c.2120C>A p.S707Y | Missense Mutation (SNP) | VAF 23/159 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.564); called by muse, mutect2, varscan2
- VWA3A | c.710G>T p.W237L | Missense Mutation (SNP) | VAF 46/212 reads (22%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.677); called by muse, mutect2, varscan2
- WDR17 | c.1340G>A p.G447D | Missense Mutation (SNP) | VAF 24/171 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- WDR64 | c.644G>A p.C215Y | Missense Mutation (SNP) | VAF 62/492 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); called by muse, varscan2
- WDR72 | c.898C>T p.L300F | Missense Mutation (SNP) | VAF 30/259 reads (12%) | SIFT tolerated (0.06); PolyPhen benign (0.071); called by muse, mutect2, varscan2
- ZADH2 | c.969T>A p.C323* | Nonsense Mutation (SNP) | VAF 28/235 reads (12%) | called by muse, mutect2, varscan2
- ZBBX | c.1061G>A p.C354Y | Missense Mutation (SNP) | VAF 40/167 reads (24%) | SIFT tolerated (0.47); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- ZBBX | c.371G>T p.C124F | Missense Mutation (SNP) | VAF 18/151 reads (12%) | SIFT tolerated (0.35); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ZBTB20 | c.1553del p.G518Afs*23 (on ENST00000474710 / NM_001164342.2; = p.G445Afs*23 on NM_015642.6 and 4 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 98/392 reads (25%) | called by mutect2, pindel, varscan2
- ZFP42 | c.368T>A p.M123K | Missense Mutation (SNP) | VAF 26/127 reads (20%) | SIFT tolerated (0.8); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- ZNF143 | c.262G>T p.V88F | Missense Mutation (SNP) | VAF 46/464 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); called by muse, mutect2
- ZNF157 | c.836G>T p.C279F | Missense Mutation (SNP) | VAF 23/150 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- ZNF292 | c.7167G>T p.M2389I | Missense Mutation (SNP) | VAF 20/135 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.914); called by muse, mutect2, varscan2
- ZNF879 | c.1073G>T p.R358L | Missense Mutation (SNP) | VAF 29/246 reads (12%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.654); called by muse, mutect2, varscan2
- ZSCAN12 | c.1526del p.R509Nfs*67 | Frame Shift Del (DEL) | VAF 130/465 reads (28%) | called by mutect2, pindel, varscan2
- ABCA13 | c.3198A>G p.K1066= | Silent (SNP) | VAF 54/365 reads (15%) | called by muse, mutect2, varscan2
- ABCA13 | c.5895A>T p.T1965= | Silent (SNP) | VAF 35/215 reads (16%) | called by muse, mutect2, varscan2
- ACAN | c.7548G>A p.E2516= (on ENST00000560601 / NM_001369268.1; = p.E2478= on NM_013227.3) | Silent (SNP) | VAF 59/239 reads (25%) | called by muse, mutect2, varscan2
- ACTN2 | c.2439C>T p.S813= | Silent (SNP) | VAF 153/1044 reads (15%) | called by muse, mutect2, varscan2
- ARAP2 | c.2523C>T p.A841= | Silent (SNP) | VAF 42/233 reads (18%) | catalogued as rs1456814643; called by muse, mutect2, varscan2
- ASCL4 | c.48G>T p.S16= | Silent (SNP) | VAF 57/202 reads (28%) | catalogued as rs577263861, COSV60816687; called by muse, mutect2, varscan2
- B4GALNT1 | c.294A>G p.R98= | Silent (SNP) | VAF 139/360 reads (39%) | catalogued as rs17852705; called by muse, mutect2, varscan2
- BOD1L1 | c.4770A>G p.E1590= | Silent (SNP) | VAF 85/513 reads (17%) | called by muse, mutect2, varscan2
- C2CD2 | c.1227G>T p.T409= | Silent (SNP) | VAF 36/407 reads (9%) | called by muse, mutect2
- CCDC61 | c.588G>A p.E196= | Silent (SNP) | VAF 13/46 reads (28%) | called by muse, mutect2, varscan2
- CD79B | c.534C>T p.F178= | Silent (SNP) | VAF 108/545 reads (20%) | catalogued as rs1462991086; called by muse, mutect2, varscan2
- CDHR5 | c.828T>A p.A276= | Silent (SNP) | VAF 22/78 reads (28%) | called by muse, mutect2, varscan2
- CFAP46 | c.6987G>A p.L2329= | Silent (SNP) | VAF 37/179 reads (21%) | catalogued as rs566266323, COSV54149993; called by muse, mutect2, varscan2
- CFAP77 | c.66C>T p.R22= | Silent (SNP) | VAF 24/348 reads (7%) | catalogued as COSV57506973; called by muse, mutect2
- CGN | c.354C>T p.S118= | Silent (SNP) | VAF 10/228 reads (4%) | called by muse, mutect2
- CHI3L2 | c.909C>T p.A303= | Silent (SNP) | VAF 6/28 reads (21%) | called by muse, varscan2
- CHRM2 | c.849C>G p.S283= | Silent (SNP) | VAF 79/564 reads (14%) | catalogued as COSV57770987; called by muse, mutect2, varscan2
- CHST3 | c.486C>T p.F162= | Silent (SNP) | VAF 63/820 reads (8%) | catalogued as rs774188997, COSV64150708; called by muse, mutect2
- CLCN1 | c.1731C>A p.L577= | Silent (SNP) | VAF 47/308 reads (15%) | called by muse, mutect2, varscan2
- CLTCL1 | c.1416C>A p.P472= | Silent (SNP) | VAF 29/132 reads (22%) | called by muse, mutect2, varscan2
- CNTNAP3 | c.3207C>A p.I1069= | Silent (SNP) | VAF 32/485 reads (7%) | called by muse, mutect2, varscan2
- COL9A1 | c.534C>G p.S178= | Silent (SNP) | VAF 51/181 reads (28%) | called by muse, mutect2, varscan2
- DGKB | c.2349C>A p.G783= | Silent (SNP) | VAF 34/231 reads (15%) | called by muse, mutect2, varscan2
- DLG2 | c.1053G>T p.V351= | Silent (SNP) | VAF 41/231 reads (18%) | called by muse, mutect2, varscan2
- DNAH3 | c.5493C>A p.I1831= | Silent (SNP) | VAF 110/585 reads (19%) | called by muse, mutect2, varscan2
- EXOC2 | c.1683G>A p.S561= | Silent (SNP) | VAF 28/200 reads (14%) | catalogued as rs763029354, COSV100032328; called by muse, mutect2, varscan2
- FAM189A1 | c.1026C>A p.L342= | Silent (SNP) | VAF 18/210 reads (9%) | called by muse, mutect2
- FBN2 | c.525T>C p.C175= | Silent (SNP) | VAF 53/370 reads (14%) | called by muse, mutect2, varscan2
- FGF4 | c.102A>C p.A34= | Silent (SNP) | VAF 44/228 reads (19%) | called by muse, varscan2
- FGFR2 | c.1533G>T p.A511= | Silent (SNP) | VAF 74/506 reads (15%) | called by muse, mutect2, varscan2
- FTMT | c.60C>A p.R20= | Silent (SNP) | VAF 53/318 reads (17%) | catalogued as rs199752019; called by muse, mutect2, varscan2
- FUT7 | c.288C>T p.R96= | Silent (SNP) | VAF 15/86 reads (17%) | catalogued as rs140687996; called by muse, mutect2, varscan2
- GALNT18 | c.1794C>A p.I598= | Silent (SNP) | VAF 23/244 reads (9%) | called by muse, mutect2
- GALNTL6 | c.1248T>A p.S416= | Silent (SNP) | VAF 90/501 reads (18%) | called by muse, mutect2, varscan2
- GIMAP1-GIMAP5 | c.465C>T p.S155= | Silent (SNP) | VAF 118/835 reads (14%) | called by muse, mutect2, varscan2
- GLI2 | c.975C>T p.A325= | Silent (SNP) | VAF 55/273 reads (20%) | catalogued as COSV100083322; called by muse, mutect2, varscan2
- GLRX | c.96C>A p.I32= | Silent (SNP) | VAF 129/691 reads (19%) | catalogued as COSV52987232; called by muse, mutect2, varscan2
- GPATCH8 | c.2841G>T p.R947= | Silent (SNP) | VAF 94/406 reads (23%) | called by muse, mutect2, varscan2
- GRIK4 | c.2652G>T p.T884= | Silent (SNP) | VAF 55/228 reads (24%) | called by muse, mutect2, varscan2
- HEATR4 | c.1179A>G p.E393= | Silent (SNP) | VAF 22/95 reads (23%) | called by muse, mutect2, varscan2
- HYDIN | c.1324T>C p.L442= | Silent (SNP) | VAF 5/15 reads (33%) | called by mutect2, varscan2
- ITGBL1 | c.1113C>A p.L371= | Silent (SNP) | VAF 97/327 reads (30%) | catalogued as rs767166554, COSV66008208; called by muse, mutect2, varscan2
- ITPRID1 | c.2997C>A p.T999= | Silent (SNP) | VAF 83/555 reads (15%) | called by muse, mutect2, varscan2
- KALRN | c.795C>T p.R265= | Silent (SNP) | VAF 52/258 reads (20%) | called by muse, mutect2, varscan2
- KCNK13 | c.591C>T p.V197= | Silent (SNP) | VAF 20/284 reads (7%) | called by muse, mutect2
- KIAA2012 | c.1401G>A p.A467= | Silent (SNP) | VAF 26/420 reads (6%) | catalogued as rs530562614, COSV99862590; called by muse, mutect2
- KIF21A | c.4113A>G p.V1371= (on ENST00000361418 / NM_001378440.1; = p.V1358= on NM_017641.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 84/246 reads (34%) | catalogued as rs767617333; called by muse, mutect2, varscan2
- KIF21B | c.1428G>C p.A476= | Silent (SNP) | VAF 129/476 reads (27%) | catalogued as COSV59767848; called by muse, mutect2, varscan2
- KIF2B | c.1140C>A p.G380= | Silent (SNP) | VAF 86/537 reads (16%) | called by muse, mutect2, varscan2
- KIT | c.2085A>G p.E695= | Silent (SNP) | VAF 39/182 reads (21%) | called by muse, mutect2, varscan2
- KRT79 | c.1311G>C p.L437= | Silent (SNP) | VAF 127/372 reads (34%) | called by muse, mutect2, varscan2
- KRTAP10-4 | c.963C>A p.V321= | Silent (SNP) | VAF 42/417 reads (10%) | called by muse, mutect2, varscan2
- LAMA5 | c.1266G>T p.S422= | Silent (SNP) | VAF 26/132 reads (20%) | called by muse, mutect2, varscan2
- LCE1F | c.90C>T p.P30= | Silent (SNP) | VAF 86/408 reads (21%) | catalogued as rs754008367, COSV57669689; called by muse, mutect2, varscan2
- LGALSL | c.360A>T p.P120= | Silent (SNP) | VAF 7/30 reads (23%) | called by muse, mutect2
- LRRC4C | c.987G>A p.R329= | Silent (SNP) | VAF 61/347 reads (18%) | catalogued as COSV53437691; called by muse, mutect2, varscan2
- LRRC4C | c.717C>T p.F239= | Silent (SNP) | VAF 20/242 reads (8%) | called by muse, mutect2
- MATK | c.165C>A p.T55= (on ENST00000310132 / NM_139355.3; = p.T56= on NM_002378.4) | Silent (SNP) | VAF 17/101 reads (17%) | called by muse, mutect2, varscan2
- MMP26 | c.480T>C p.D160= | Silent (SNP) | VAF 22/67 reads (33%) | catalogued as rs1177052077; called by mutect2, varscan2
- MRGPRD | c.102C>T p.A34= | Silent (SNP) | VAF 14/139 reads (10%) | catalogued as rs189891972; called by muse, mutect2, varscan2
- MROH2B | c.1407C>A p.P469= | Silent (SNP) | VAF 32/225 reads (14%) | called by muse, varscan2
- MRPL24 | c.261C>A p.V87= | Silent (SNP) | VAF 104/551 reads (19%) | catalogued as COSV61975520; called by muse, mutect2, varscan2
- MUC16 | c.41527A>C p.R13843= | Silent (SNP) | VAF 95/455 reads (21%) | called by muse, mutect2, varscan2
- MUC16 | c.27600C>A p.P9200= | Silent (SNP) | VAF 77/269 reads (29%) | called by muse, mutect2, varscan2
- MYO18B | c.3573C>A p.I1191= | Silent (SNP) | VAF 31/169 reads (18%) | called by muse, mutect2, varscan2
- NCAPG | c.1114T>C p.L372= | Silent (SNP) | VAF 8/48 reads (17%) | catalogued as rs1390757093; called by muse, mutect2
- NGF | c.690G>T p.V230= | Silent (SNP) | VAF 18/90 reads (20%) | called by muse, mutect2, varscan2
- NGF | c.153C>A p.A51= | Silent (SNP) | VAF 51/187 reads (27%) | called by muse, mutect2, varscan2
- NID2 | c.3090C>T p.Y1030= | Silent (SNP) | VAF 31/128 reads (24%) | catalogued as rs773630715, COSV53494408; called by muse, mutect2, varscan2
- NRBP2 | c.24G>A p.P8= | Silent (SNP) | VAF 12/117 reads (10%) | called by muse, mutect2, varscan2
- NRXN2 | c.216C>A p.G72= | Silent (SNP) | VAF 84/453 reads (19%) | called by muse, mutect2, varscan2
- OGDHL | c.1344G>T p.P448= | Silent (SNP) | VAF 40/191 reads (21%) | catalogued as rs770910107, COSV100934478, COSV65103977; called by muse, mutect2, varscan2
- OR4D10 | c.231A>T p.T77= | Silent (SNP) | VAF 29/124 reads (23%) | called by muse, mutect2, varscan2
- OR6N2 | c.204C>T p.F68= | Silent (SNP) | VAF 39/303 reads (13%) | catalogued as rs753132459, COSV59413032; called by muse, mutect2, varscan2
- OR9A4 | c.372G>A p.V124= | Silent (SNP) | VAF 26/310 reads (8%) | called by muse, mutect2
- OTOG | c.7002C>A p.I2334= | Silent (SNP) | VAF 47/246 reads (19%) | called by muse, mutect2, varscan2
- PCDH10 | c.1554C>T p.I518= | Silent (SNP) | VAF 49/263 reads (19%) | catalogued as rs138396564, COSV52101354; called by muse, mutect2, varscan2
- PDE9A | c.1401C>A p.V467= | Silent (SNP) | VAF 14/269 reads (5%) | catalogued as COSV52331433; called by muse, mutect2
- PERM1 | c.1386C>A p.T462= | Silent (SNP) | VAF 27/102 reads (26%) | called by muse, mutect2, varscan2
- PGAP4 | c.381G>C p.R127= | Silent (SNP) | VAF 18/88 reads (20%) | called by muse, mutect2, varscan2
- PHGDH | c.489G>C p.R163= | Silent (SNP) | VAF 42/492 reads (9%) | catalogued as COSV101025205; called by muse, mutect2
- PLEC | c.7902T>A p.S2634= (on ENST00000322810 / NM_201380.4; = p.S2524= on NM_000445.5) | Silent (SNP) | VAF 53/279 reads (19%) | called by muse, mutect2, varscan2
- PLEKHB2 | c.783C>A p.L261= | Silent (SNP) | VAF 8/30 reads (27%) | called by mutect2, varscan2
- PLXNA4 | c.1755G>A p.P585= | Silent (SNP) | VAF 72/459 reads (16%) | catalogued as rs749277155, COSV58142069; called by muse, mutect2, varscan2
- PRDM10 | c.1218G>T p.G406= | Silent (SNP) | VAF 57/301 reads (19%) | catalogued as rs774932832; called by muse, mutect2, varscan2
- PRLR | c.1509C>T p.S503= | Silent (SNP) | VAF 57/269 reads (21%) | catalogued as rs368647716; called by muse, mutect2, varscan2
- PRSS54 | c.549C>A p.V183= | Silent (SNP) | VAF 50/285 reads (18%) | called by muse, mutect2, varscan2
- PSPH | c.609A>G p.Q203= | Silent (SNP) | VAF 89/450 reads (20%) | catalogued as rs752178752, COSV51914195; called by muse, mutect2, varscan2
- PTPN3 | c.31A>C p.R11= | Silent (SNP) | VAF 18/194 reads (9%) | called by muse, mutect2
- PTPRN | c.84C>T p.R28= | Silent (SNP) | VAF 26/189 reads (14%) | called by muse, mutect2, varscan2
- RBBP8 | c.1044T>G p.P348= | Silent (SNP) | VAF 28/252 reads (11%) | called by muse, mutect2, varscan2
- RGS7 | c.774A>G p.L258= | Silent (SNP) | VAF 31/412 reads (8%) | called by muse, mutect2
- RUFY3 | c.171C>A p.T57= | Silent (SNP) | VAF 17/75 reads (23%) | called by muse, mutect2
- SBF1 | c.1548C>T p.I516= | Silent (SNP) | VAF 13/127 reads (10%) | catalogued as rs747733689; called by muse, mutect2, varscan2
- SH3D21 | c.957T>G p.P319= (on ENST00000453908 / NM_001162530.2; = p.P208= on NM_024676.5) | Silent (SNP) | VAF 60/255 reads (24%) | called by muse, mutect2, varscan2
- SIM2 | c.528C>T p.T176= | Silent (SNP) | VAF 26/237 reads (11%) | called by muse, mutect2, varscan2
- SLC26A2 | c.2013C>T p.R671= | Silent (SNP) | VAF 31/230 reads (13%) | called by muse, mutect2, varscan2
- SLC35E4 | c.237C>A p.P79= | Silent (SNP) | VAF 17/74 reads (23%) | called by muse, mutect2, varscan2
- SLC8A2 | c.381G>T p.T127= | Silent (SNP) | VAF 111/490 reads (23%) | called by muse, mutect2, varscan2
- SLC9A3 | c.811C>T p.L271= | Silent (SNP) | VAF 47/254 reads (19%) | called by muse, mutect2, varscan2
- SPIN2A | c.390C>T p.G130= | Silent (SNP) | VAF 71/426 reads (17%) | called by muse, mutect2, varscan2
- TENM1 | c.6999C>A p.V2333= | Silent (SNP) | VAF 20/101 reads (20%) | called by muse, mutect2, varscan2
- TENM3 | c.1998G>C p.T666= | Silent (SNP) | VAF 86/419 reads (21%) | catalogued as COSV69320915; called by muse, mutect2, varscan2
- TMEM266 | c.45C>A p.A15= | Silent (SNP) | VAF 49/259 reads (19%) | called by muse, mutect2, varscan2
- TRIM67 | c.870G>T p.G290= | Silent (SNP) | VAF 65/214 reads (30%) | called by muse, mutect2, varscan2
- TSPOAP1 | c.3198G>T p.S1066= | Silent (SNP) | VAF 71/311 reads (23%) | called by muse, mutect2, varscan2
- TSPOAP1 | c.2262C>T p.S754= | Silent (SNP) | VAF 14/43 reads (33%) | catalogued as rs775210061, COSV99271170; called by mutect2, varscan2
- TTN | c.58813T>C p.L19605= (on ENST00000591111; = p.L12181= on NM_003319.4) | Silent (SNP) | VAF 15/59 reads (25%) | called by muse, mutect2, varscan2
- TUB | c.336G>A p.A112= (on ENST00000299506 / NM_177972.3; = p.A167= on NM_003320.4) | Silent (SNP) | VAF 52/216 reads (24%) | catalogued as rs182640954; ClinVar: likely benign; called by muse, mutect2, varscan2
- TVP23A | c.438G>A p.L146= | Silent (SNP) | VAF 34/140 reads (24%) | called by muse, mutect2, varscan2
- UBXN1 | c.33C>T p.I11= | Silent (SNP) | VAF 29/150 reads (19%) | called by muse, mutect2, varscan2
- VGLL1 | c.471A>G p.P157= | Silent (SNP) | VAF 108/442 reads (24%) | catalogued as rs970659066; called by muse, mutect2, varscan2
- VN1R5 | c.435C>A p.I145= | Silent (SNP) | VAF 15/104 reads (14%) | called by muse, mutect2, varscan2
- VSX2 | c.1047G>C p.A349= | Silent (SNP) | VAF 21/77 reads (27%) | catalogued as COSV56217011; called by muse, mutect2, varscan2
- Z83844.2 | c.351T>C p.H117= | Silent (SNP) | VAF 102/556 reads (18%) | called by muse, varscan2
- ZC3HAV1 | c.2574G>T p.T858= | Silent (SNP) | VAF 66/443 reads (15%) | called by muse, mutect2, varscan2
- ZFHX4 | c.8776C>A p.R2926= | Silent (SNP) | VAF 30/207 reads (14%) | catalogued as COSV50480182, COSV50759034; called by muse, mutect2, varscan2
- ZFPM2 | c.2451T>A p.T817= | Silent (SNP) | VAF 108/583 reads (19%) | called by muse, mutect2, varscan2
- ZNF727 | c.30T>A p.A10= | Silent (SNP) | VAF 86/455 reads (19%) | called by muse, mutect2, varscan2
- AC024598.1 | c.1130-923G>T | Intron (SNP) | VAF 70/538 reads (13%) | called by muse, mutect2, varscan2
- AC114741.1 | n.175C>A | RNA (SNP) | VAF 76/459 reads (17%) | called by muse, mutect2, varscan2
- ADAM21P1 | n.1023T>A | RNA (SNP) | VAF 74/888 reads (8%) | called by muse, mutect2
- ADD3-AS1 | n.4136C>A | RNA (SNP) | VAF 48/315 reads (15%) | called by muse, mutect2, varscan2
- ADGRL2 | c.3625+849G>T | Intron (SNP) | VAF 8/68 reads (12%) | called by muse, mutect2
- AL121758.1 | c.*767C>T | 3'UTR (SNP) | VAF 35/146 reads (24%) | called by muse, mutect2, varscan2
- BIRC8 | n.1323C>A | RNA (SNP) | VAF 53/219 reads (24%) | called by muse, mutect2, varscan2
- CHMP1A | c.381+50G>T | Intron (SNP) | VAF 55/226 reads (24%) | called by muse, mutect2, varscan2
- CLNK | c.-18C>T | 5'UTR (SNP) | VAF 22/99 reads (22%) | catalogued as rs762444234; called by muse, mutect2, varscan2
- COX4I2 | c.*34C>A | 3'UTR (SNP) | VAF 35/168 reads (21%) | catalogued as COSV101064197; called by muse, mutect2, varscan2
- DCAF17 | c.*2009G>T | 3'UTR (SNP) | VAF 120/763 reads (16%) | called by muse, mutect2, varscan2
- FER1L4 | n.4013C>A | RNA (SNP) | VAF 19/308 reads (6%) | called by muse, mutect2
- FGA | c.1891+40C>A | Intron (SNP) | VAF 9/68 reads (13%) | catalogued as rs370440460; called by muse, mutect2, varscan2
- FLT4 | c.3331+36G>T | Intron (SNP) | VAF 66/384 reads (17%) | called by muse, mutect2, varscan2
- FMN1 | c.2044-1990del | Intron (DEL) | VAF 17/155 reads (11%) | called by mutect2, pindel, varscan2
- GABRB3 | chr15:26773692 G>A | 5'Flank (SNP) | VAF 45/451 reads (10%) | called by muse, mutect2, varscan2
- GPRC5C | chr17:74449370 G>T | 3'Flank (SNP) | VAF 29/168 reads (17%) | called by muse, mutect2, varscan2
- HARS2 | c.183+13G>T | Intron (SNP) | VAF 78/499 reads (16%) | called by muse, mutect2, varscan2
- IGFN1 | c.1241+1436G>T | Intron (SNP) | VAF 44/104 reads (42%) | catalogued as rs1172151819, COSV55186779; called by muse, mutect2, varscan2
- KDELR2 | c.*127G>T | 3'UTR (SNP) | VAF 53/288 reads (18%) | called by muse, mutect2, varscan2
- LCP2 | c.324+11T>A | Intron (SNP) | VAF 48/404 reads (12%) | called by muse, mutect2, varscan2
- LINC00868 | n.675C>A | RNA (SNP) | VAF 110/545 reads (20%) | called by muse, mutect2, varscan2
- LINC01118 | n.1129C>A | RNA (SNP) | VAF 66/394 reads (17%) | catalogued as rs550039530; called by muse, mutect2, varscan2
- LINC01561 | n.569C>A | RNA (SNP) | VAF 20/98 reads (20%) | called by mutect2, varscan2
- LINC02610 | n.2946del | RNA (DEL) | VAF 43/203 reads (21%) | called by mutect2, pindel, varscan2
- LMBR1 | c.*2941G>C | 3'UTR (SNP) | VAF 126/439 reads (29%) | called by muse, mutect2, varscan2
- LMBRD2 | c.-58+3655G>T | Intron (SNP) | VAF 14/122 reads (11%) | called by muse, mutect2
- MIR1-1HG-AS1 | n.630G>C | RNA (SNP) | VAF 112/435 reads (26%) | called by muse, mutect2, varscan2
- MIR509-1 | n.56G>T | RNA (SNP) | VAF 41/272 reads (15%) | called by muse, mutect2, varscan2
- MTX1 | chr1:155216929 C>A | 3'Flank (SNP) | VAF 77/470 reads (16%) | catalogued as rs763941747; called by muse, mutect2, varscan2
- MUC2 | chr11:1094632 C>A | 3'Flank (SNP) | VAF 20/76 reads (26%) | called by muse, varscan2
- OR10AB1P | n.1010G>T | RNA (SNP) | VAF 87/452 reads (19%) | called by muse, mutect2, varscan2
- PABPC1P2 | n.828C>A | RNA (SNP) | VAF 46/406 reads (11%) | called by muse, mutect2, varscan2
- PCDHB5 | c.-1A>T | 5'UTR (SNP) | VAF 5/31 reads (16%) | called by muse, mutect2, varscan2
- PPP2R1B | c.307-170G>T | Intron (SNP) | VAF 14/97 reads (14%) | called by muse, mutect2, varscan2
- PRKCB | c.205+31726C>A | Intron (SNP) | VAF 28/165 reads (17%) | called by muse, mutect2, varscan2
- RASSF6 | c.-2C>G | 5'UTR (SNP) | VAF 28/95 reads (29%) | called by muse, mutect2, varscan2
- RNA5-8SP2 | chr16:34159791 C>A | 5'Flank (SNP) | VAF 39/231 reads (17%) | catalogued as rs752034309; called by muse, mutect2, varscan2
- RNF25 | c.-12G>T | 5'UTR (SNP) | VAF 70/289 reads (24%) | called by muse, mutect2, varscan2
- RNU7-174P | chr8:80559221 G>T | 5'Flank (SNP) | VAF 154/678 reads (23%) | called by muse, mutect2, varscan2
- SEC16B | c.1775+42A>G | Intron (SNP) | VAF 71/458 reads (16%) | called by muse, mutect2, varscan2
- SERPINA3 | c.*29G>A | 3'UTR (SNP) | VAF 43/216 reads (20%) | catalogued as rs935055768; called by muse, mutect2, varscan2
- SMIM3 | c.-310G>A | 5'UTR (SNP) | VAF 27/134 reads (20%) | catalogued as rs367660575; called by muse, mutect2, varscan2
- SPATA16 | c.*12C>A | 3'UTR (SNP) | VAF 80/409 reads (20%) | called by muse, mutect2, varscan2
- SPG11 | c.3686+32A>G | Intron (SNP) | VAF 25/302 reads (8%) | called by muse, mutect2
- SYTL2 | c.1459+2985G>T | Intron (SNP) | VAF 17/108 reads (16%) | called by muse, mutect2, varscan2
- TMEM135 | c.*4543A>G | 3'UTR (SNP) | VAF 22/230 reads (10%) | called by muse, mutect2
- TNFAIP8 | c.32-1412G>A | Intron (SNP) | VAF 41/355 reads (12%) | called by muse, mutect2, varscan2
- URB1 | c.664+1200G>C | Intron (SNP) | VAF 44/319 reads (14%) | called by muse, mutect2, varscan2
- UROS | c.394+4401A>G | Intron (SNP) | VAF 48/349 reads (14%) | catalogued as rs778743994; called by muse, mutect2, varscan2
- ZEB2 | c.73+5089G>T | Intron (SNP) | VAF 20/149 reads (13%) | called by muse, mutect2, varscan2
- ZFAT | c.20-17096A>T | Intron (SNP) | VAF 11/33 reads (33%) | called by muse, mutect2, varscan2
- ZFYVE1 | c.*1153G>T | 3'UTR (SNP) | VAF 26/217 reads (12%) | called by muse, mutect2, varscan2
- ZNF747 | c.*419A>G | 3'UTR (SNP) | VAF 26/121 reads (21%) | catalogued as rs545732598; called by muse, mutect2, varscan2
